Somatic mutation profile of tumor specimen C3L-02622-01 (aliquot CPT0202860007) from CPTAC case C3L-02622, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 42.7 years (15,590 days).
Specimen C3L-02622-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 263a212e-3be3-4b51-96ab-38959ed11f73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02622-31 (Blood Derived Normal), aliquot CPT0203020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24b1553e-d8d0-43b2-a86a-1c7435e9a5b1

The open-access MAF lists 620 somatic variants for this specimen: 419 protein-altering or splice-affecting, 186 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 367, Silent 186, Nonsense Mutation 36, Intron 8, Splice Region 7, Splice Site 4, 5'Flank 4, In Frame Del 2, Frame Shift Del 2, Frame Shift Ins 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 194/362 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MYH7 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 110/300 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913633, CM930502, COSV62522280; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NCF2 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 104/271 reads (38%) | catalogued as rs766745748, CM101806, COSV100838886; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 71/213 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RSPH3 | c.1192C>T p.R398* (on ENST00000252655; = p.R256* on NM_031924.8) | Nonsense Mutation (SNP) | VAF 28/263 reads (11%) | catalogued as rs796052118, CM157017; ClinVar: pathogenic; called by muse, mutect2, varscan2
- THSD7B | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 80/261 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV55689123, COSV55699747; called by muse, mutect2, varscan2
- A2ML1 | c.2386C>T p.L796F | Missense Mutation (SNP) | VAF 109/354 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1481164167; called by muse, mutect2, varscan2
- ABCC6 | c.4252C>T p.R1418W | Missense Mutation (SNP) | VAF 131/441 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs59588658; called by muse, mutect2, varscan2
- ADAM18 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99695719; called by muse, mutect2, varscan2
- ADAM7 | c.1639C>T p.L547F | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV51543535; called by muse, mutect2, varscan2
- ADAMTS7 | c.3052G>A p.E1018K | Missense Mutation (SNP) | VAF 138/413 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs373018837, COSV101183036; called by muse, mutect2, varscan2
- ADAMTS8 | c.1752G>A p.G584= | Splice Region (SNP) | VAF 67/201 reads (33%) | catalogued as COSV57291945; called by muse, mutect2, varscan2
- ADGRG4 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as COSV54954382, COSV54964615; called by muse, mutect2, varscan2
- ADGRL2 | c.4058C>T p.S1353F (on ENST00000370717 / NM_001366005.1; = p.S1297F on NM_012302.4) | Missense Mutation (SNP) | VAF 101/359 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV54698050, COSV99046898; called by muse, mutect2, varscan2
- ADGRV1 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV101316089; called by muse, mutect2, varscan2
- ADGRV1 | c.10464G>A p.M3488I | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV101315805; called by muse, mutect2, varscan2
- ADNP2 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 129/423 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.134); catalogued as rs1211532606; called by muse, mutect2, varscan2
- AIRE | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 88/314 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs763636007, CM085227, CM157142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKR1C2 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV66334675; called by muse, mutect2, varscan2
- ALDH16A1 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as rs1282660176; called by muse, mutect2, varscan2
- AMY1C | c.1003C>T p.L335= | Splice Region (SNP) | VAF 33/654 reads (5%) | catalogued as COSV100915244; called by muse, mutect2
- ARFGEF3 | c.5945G>A p.G1982D | Missense Mutation (SNP) | VAF 142/328 reads (43%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.006); catalogued as rs1562220465; called by muse, mutect2, varscan2
- ARHGAP15 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 65/216 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV99711035; called by muse, mutect2, varscan2
- ARHGEF26 | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV62843841; called by muse, mutect2, varscan2
- ARHGEF33 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 75/327 reads (23%) | catalogued as COSV67256306; called by muse, mutect2, varscan2
- ARHGEF37 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 157/440 reads (36%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.867); catalogued as rs754074265; called by muse, mutect2, varscan2
- BNC2 | c.1946C>T p.T649I | Missense Mutation (SNP) | VAF 102/323 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV66143862; called by muse, mutect2, varscan2
- BTAF1 | c.3703C>T p.Q1235* | Nonsense Mutation (SNP) | VAF 120/349 reads (34%) | catalogued as COSV56437564; called by muse, mutect2, varscan2
- BTG4 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 99/315 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749155001; called by muse, mutect2, varscan2
- C6 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 68/231 reads (29%) | catalogued as rs778044260, COSV54706799; called by muse, mutect2, varscan2
- C8orf74 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 95/272 reads (35%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.848); catalogued as rs1460277883; called by mutect2, varscan2
- CAPN1 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 111/368 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382148378; called by muse, mutect2, varscan2
- CCDC142 | c.2140C>T p.P714S (on ENST00000393965 / NM_001365575.2; = p.P707S on NM_032779.4) | Missense Mutation (SNP) | VAF 136/403 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as rs560738510, COSV50688949; called by muse, mutect2, varscan2
- CCDC18 | c.3743C>T p.S1248F (on ENST00000343253 / NM_001306076.1; = p.S1249F on NM_206886.4) | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100159194; called by muse, mutect2, varscan2
- CD1E | c.389G>C p.R130T | Missense Mutation (SNP) | VAF 96/319 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100936875; called by muse, mutect2, varscan2
- CEACAM20 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV57601217; called by muse, mutect2
- CEP126 | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 60/156 reads (38%) | catalogued as COSV54828941; called by muse, mutect2, varscan2
- CETP | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 95/345 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs536221680, COSV52361826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD3 | c.2969C>T p.P990L | Missense Mutation (SNP) | VAF 92/195 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100390946; called by muse, mutect2, varscan2
- CILP2 | c.2443G>A p.G815S | Missense Mutation (SNP) | VAF 175/547 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs758866374; called by muse, mutect2, varscan2
- CNTN3 | c.1919C>T p.S640F | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV55162661; called by muse, mutect2, varscan2
- CNTNAP3 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 73/221 reads (33%) | catalogued as COSV52663134; called by muse, mutect2, varscan2
- CNTNAP4 | c.3664C>T p.H1222Y | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.642); catalogued as COSV56690176; called by muse, mutect2, varscan2
- COL11A1 | c.3655G>A p.G1219R | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100617924; called by muse, mutect2, varscan2
- COL4A3 | c.4153G>A p.G1385R | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67418134; called by muse, mutect2, varscan2
- COL4A5 | c.4045G>A p.E1349K | Missense Mutation (SNP) | VAF 128/221 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as CD115550, COSV60364536; called by muse, mutect2, varscan2
- COL5A1 | c.1810G>A p.G604R | Missense Mutation (SNP) | VAF 146/501 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65675695; called by muse, mutect2, varscan2
- CR2 | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 128/338 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs544264495, COSV65506386; called by muse, mutect2, varscan2
- CRYBG2 | c.1132C>T p.H378Y | Missense Mutation (SNP) | VAF 150/424 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.062); catalogued as rs1272575344; called by muse, mutect2, varscan2
- CSMD3 | c.1537G>A p.D513N (on ENST00000297405 / NM_001363185.1; = p.D409N on NM_052900.3) | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.84); catalogued as COSV99826252; called by muse, mutect2, varscan2
- CTLA4 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 88/280 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361102216, COSV55593443; called by muse, mutect2, varscan2
- CYP2C19 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as rs867067400, COSV64907708; called by muse, mutect2
- CYP2C19 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 121/375 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1232142122, COSV64906940; called by muse, mutect2, varscan2
- CYP3A7 | c.473G>A p.R158K | Missense Mutation (SNP) | VAF 233/389 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1390015837, COSV60480593, COSV60482433; called by muse, mutect2, varscan2
- DCC | c.728T>C p.L243P | Missense Mutation (SNP) | VAF 88/333 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV59119739; called by muse, mutect2, varscan2
- DDI1 | c.955T>C p.S319P | Missense Mutation (SNP) | VAF 96/337 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56375461; called by muse, mutect2, varscan2
- DHRS7C | c.830A>G p.N277S (on ENST00000330255 / NM_001220493.2; = p.N276S on NM_001105571.3) | Missense Mutation (SNP) | VAF 18/523 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.422); catalogued as COSV57650272; called by muse, mutect2
- DHX37 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 92/322 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs140263914; called by muse, mutect2
- DLEC1 | c.2102C>T p.S701F | Missense Mutation (SNP) | VAF 83/267 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100341112; called by muse, mutect2, varscan2
- DMRT2 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 24/484 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1340966544, COSV52401737; called by muse, mutect2
- DNAH1 | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1316385405; called by muse, mutect2, varscan2
- DNAH5 | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 89/306 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV54221592; called by muse, mutect2, varscan2
- DNAH9 | c.9667G>A p.D3223N | Missense Mutation (SNP) | VAF 122/406 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.139); catalogued as rs1161820565; called by muse, mutect2, varscan2
- DNAJC18 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 99/310 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs201230885, COSV57415758; called by muse, mutect2, varscan2
- DSCAM | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 70/246 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as rs267606128, COSV68029375; called by muse, mutect2, varscan2
- EFL1 | c.3280G>A p.V1094I | Missense Mutation (SNP) | VAF 132/378 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as rs1231593347; called by muse, mutect2, varscan2
- EHBP1 | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 78/318 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99861514; called by muse, mutect2, varscan2
- ELN | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 132/704 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); catalogued as rs1554679817; called by muse, mutect2
- ETV1 | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 64/307 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54141811, COSV54150204; called by muse, mutect2, varscan2
- FAM83F | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 147/265 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as COSV100328814; called by muse, mutect2, varscan2
- FCAR | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 148/455 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0.191); catalogued as rs868551254; called by muse, mutect2, varscan2
- FETUB | c.380G>A p.S127N | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as rs1279758463; called by muse, mutect2, varscan2
- FGF19 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 97/278 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs770504584, COSV53736278, COSV99594383; called by muse, mutect2, varscan2
- FGF4 | c.141G>A p.W47* | Nonsense Mutation (SNP) | VAF 150/493 reads (30%) | catalogued as COSV99395501; called by muse, mutect2, varscan2
- FLG | c.1283A>C p.H428P | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1267120455; called by muse, mutect2
- FRG2B | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 67/584 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.316); catalogued as COSV71042699, COSV71043031; called by muse, mutect2
- GAMT | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 112/383 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1397834128; called by muse, varscan2
- GDPD3 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 133/388 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53774813; called by muse, mutect2, varscan2
- GEMIN7 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 129/439 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762849310; called by muse, mutect2, varscan2
- GFER | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 125/357 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180176254, COSV50191386; called by muse, mutect2, varscan2
- GOLGA8M | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 104/426 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV61013024; called by muse, mutect2, varscan2
- GPATCH8 | c.1374_1377del p.S459Kfs*11 | Frame Shift Del (DEL) | VAF 118/417 reads (28%) | catalogued as rs748631863; called by mutect2, pindel, varscan2
- GRM2 | c.1984G>A p.G662S | Missense Mutation (SNP) | VAF 156/463 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs756895347; called by muse, mutect2, varscan2
- GRM6 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 98/296 reads (33%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.716); catalogued as rs768585935, COSV51437290; called by muse, mutect2, varscan2
- HERC1 | c.11812G>A p.E3938K | Missense Mutation (SNP) | VAF 23/412 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs368216902; called by muse, mutect2
- HKDC1 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 98/332 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.183); catalogued as rs1438368330; called by muse, varscan2
- HOXA5 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs1344390609, COSV56074174; called by muse, mutect2
- HS3ST4 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 147/443 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs769841364, COSV58807725; called by muse, mutect2, varscan2
- HTR2C | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 137/193 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868979642; called by muse, mutect2, varscan2
- IDO1 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53713547; called by muse, mutect2, varscan2
- IQSEC3 | c.3034G>A p.D1012N (on ENST00000538872 / NM_001170738.2; = p.D709N on NM_015232.1) | Missense Mutation (SNP) | VAF 138/420 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs782029989, COSV58283945; called by muse, mutect2, varscan2
- ITPKC | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 156/462 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV54574877; called by muse, mutect2, varscan2
- KCNH1 | c.2944G>A p.E982K (on ENST00000271751 / NM_172362.3; = p.E955K on NM_002238.4) | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.195); catalogued as COSV55100754; called by muse, mutect2, varscan2
- KCNJ3 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 100/346 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as COSV54536232; called by muse, mutect2, varscan2
- KIF26A | c.4409C>T p.S1470F | Missense Mutation (SNP) | VAF 213/630 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs370850949; called by muse, mutect2, varscan2
- KRT81 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 58/276 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59810585; called by muse, mutect2
- KSR2 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 97/361 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs373055394; called by muse, mutect2, varscan2
- LAMB3 | c.3139C>T p.R1047C | Missense Mutation (SNP) | VAF 115/378 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs750476293, COSV50522604; called by muse, mutect2, varscan2
- LGSN | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.786); catalogued as rs1210441333; called by muse, mutect2, varscan2
- LGSN | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 100/359 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs778586283, COSV101040483, COSV65726977; called by muse, mutect2, varscan2
- LILRA5 | c.861G>A p.W287* | Nonsense Mutation (SNP) | VAF 32/338 reads (9%) | catalogued as rs779366333; called by muse, mutect2
- LIMCH1 | c.3218G>A p.R1073Q | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1393633123, COSV58294365; called by muse, mutect2, varscan2
- LIMK1 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 217/426 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as rs148676592; called by muse, mutect2, varscan2
- LMBR1 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 177/335 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs765557728, COSV62218224; called by muse, mutect2, varscan2
- LOXHD1 | c.4708G>A p.D1570N | Missense Mutation (SNP) | VAF 114/359 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs747408197, COSV56061786; called by muse, mutect2, varscan2
- LRRC27 | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 118/359 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs749191127; called by muse, mutect2, varscan2
- LRRC66 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 59/252 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs769681602; called by muse, mutect2, varscan2
- LSP1 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 131/453 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.831); catalogued as rs767061907; called by muse, mutect2, varscan2
- MALL | c.126G>A p.W42* | Nonsense Mutation (SNP) | VAF 59/434 reads (14%) | catalogued as rs778890730; called by muse, mutect2, varscan2
- MCM6 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 121/349 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51466608; called by muse, mutect2, varscan2
- MECOM | c.2845G>A p.E949K (on ENST00000468789 / NM_001105078.4; = p.E1137K on NM_004991.4) | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.628); catalogued as COSV99244666; called by muse, mutect2, varscan2
- MECOM | c.253C>T p.P85S (on ENST00000468789 / NM_001105078.4; = p.P273S on NM_004991.4) | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV52963255; called by muse, mutect2, varscan2
- MORC2 | c.296A>T p.Q99L (on ENST00000397641 / NM_001303256.3; = p.Q37L on NM_014941.3) | Missense Mutation (SNP) | VAF 115/210 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53196184; called by muse, mutect2, varscan2
- MROH5 | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as rs771593476; called by muse, mutect2, varscan2
- MUC12 | c.5513C>T p.S1838L (on ENST00000379442; = p.S1695L on NM_001164462.1) | Missense Mutation (SNP) | VAF 139/712 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs774881285; called by muse, varscan2
- MUC16 | c.28570G>A p.E9524K | Missense Mutation (SNP) | VAF 129/390 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.549); catalogued as COSV67445055; called by muse, mutect2, varscan2
- MUC16 | c.3149G>A p.G1050E | Missense Mutation (SNP) | VAF 139/406 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs866645734, COSV101200463; called by muse, mutect2, varscan2
- MYH1 | c.5578G>A p.E1860K | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as rs752265147; called by muse, mutect2, varscan2
- MYH14 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 112/293 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as rs1409787707; called by muse, mutect2, varscan2
- MYH2 | c.4865A>C p.K1622T | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55449987; called by muse, mutect2
- MYH2 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 82/283 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1373237213; called by muse, mutect2, varscan2
- MYLK | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 119/412 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.217); catalogued as COSV60607707, COSV60609925; called by muse, mutect2, varscan2
- MYO16 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 95/310 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779048736, COSV51821109; called by muse, mutect2, varscan2
- NEB | c.2897C>T p.S966F | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1472268201; called by muse, mutect2, varscan2
- NISCH | c.2116C>T p.R706C | Missense Mutation (SNP) | VAF 170/517 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs372251478; called by muse, varscan2
- NLRC4 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 131/376 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs141248470; called by muse, mutect2, varscan2
- NLRP2 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 157/498 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as rs1225136250; called by muse, mutect2, varscan2
- NRXN2 | c.3667G>A p.G1223S | Missense Mutation (SNP) | VAF 133/431 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99636522; called by muse, mutect2, varscan2
- NRXN3 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 147/440 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1316421578; called by muse, mutect2, varscan2
- NUDCD1 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 87/334 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53455008; called by muse, mutect2, varscan2
- NUF2 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 104/285 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as rs747173543, COSV54841988; called by muse, mutect2, varscan2
- NUTM2F | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 105/377 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.8); catalogued as rs1203778690; called by muse, mutect2, varscan2
- OLFM2 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 103/316 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as rs199678889, COSV99322060; called by muse, mutect2, varscan2
- OR10A5 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV55053159; called by muse, mutect2, varscan2
- OR10R2 | c.287T>C p.V96A | Missense Mutation (SNP) | VAF 88/321 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.117); catalogued as COSV63768408, COSV63769785; called by muse, mutect2, varscan2
- OR13C9 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 161/477 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV52241486; called by muse, mutect2, varscan2
- OR1S2 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 100/340 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV56919143; called by muse, mutect2, varscan2
- OR2C1 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 105/392 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as rs767304087; called by muse, mutect2, varscan2
- OR2G3 | c.30G>A p.M10I | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100180773, COSV60680868; called by muse, mutect2, varscan2
- OR2M5 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 115/388 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV63546077; called by muse, mutect2, varscan2
- OR2Y1 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 22/404 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs758002658; called by muse, mutect2
- OR51G2 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 120/354 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs867001321, COSV58992760; called by muse, mutect2, varscan2
- OR7A17 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 131/369 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV59414977; called by muse, mutect2, varscan2
- PCDHA4 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 129/418 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as rs532147064, COSV63539710; called by muse, mutect2, varscan2
- PCDHB16 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 93/299 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs782645618, COSV53372173; called by muse, mutect2, varscan2
- PDE8B | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 116/374 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1253291220; called by muse, mutect2, varscan2
- PER2 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 100/318 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54523793; called by muse, mutect2, varscan2
- PHRF1 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 102/293 reads (35%) | catalogued as COSV99213760; called by muse, mutect2, varscan2
- PKHD1L1 | c.2648C>T p.S883L | Missense Mutation (SNP) | VAF 91/300 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV101005810; called by muse, mutect2, varscan2
- PLCL2 | c.3367G>A p.D1123N (on ENST00000615277 / NM_001144382.2; = p.D997N on NM_015184.5) | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.058); catalogued as rs144964120; called by muse, varscan2
- PLEKHM1 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 182/579 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147167801, COSV69599071; called by muse, mutect2, varscan2
- PLPP7 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 128/455 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1242757311; called by muse, mutect2
- POLA1 | c.3925C>T p.R1309C | Missense Mutation (SNP) | VAF 77/119 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs201607896; called by muse, mutect2, varscan2
- PPP2R3C | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs200143090; called by muse, mutect2, varscan2
- PPP4R4 | c.2598-1G>A p.X866_splice | Splice Site (SNP) | VAF 63/218 reads (29%) | catalogued as COSV100003964, COSV56227313; called by muse, mutect2, varscan2
- PRSS22 | c.478A>G p.I160V | Missense Mutation (SNP) | VAF 175/529 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as rs758598271; called by muse, mutect2, varscan2
- PSD | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 83/297 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.629); catalogued as rs1015034436, COSV99193028; called by muse, mutect2
- PSG1 | c.551G>A p.G184D | Missense Mutation (SNP) | VAF 142/424 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1346316285; called by muse, mutect2, varscan2
- PTCHD3 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 143/408 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.03); catalogued as COSV71256336; called by muse, mutect2, varscan2
- PTPRN | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 106/395 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99834150; called by muse, mutect2, varscan2
- PTPRT | c.291G>T p.E97D | Missense Mutation (SNP) | VAF 21/479 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61979978; called by muse, mutect2
- RASGRF2 | c.2464C>T p.Q822* | Nonsense Mutation (SNP) | VAF 80/224 reads (36%) | catalogued as COSV99428654; called by muse, mutect2, varscan2
- RGPD3 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 96/516 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs370819784, COSV58737048; called by muse, mutect2, varscan2
- RHOA | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.811); catalogued as COSV104435088, COSV69043185; called by muse, mutect2
- RPL18 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs146179249; called by muse, mutect2, varscan2
- RTN1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 142/408 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV50728743; called by muse, mutect2, varscan2
- SCAF1 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 108/409 reads (26%) | catalogued as rs1158710132, COSV62182347; called by muse, mutect2, varscan2
- SEC23B | c.452T>A p.L151Q | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52718997; called by muse, mutect2
- SERPINA6 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 157/502 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58587104; called by muse, mutect2, varscan2
- SI | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.103); catalogued as COSV52298436; called by muse, mutect2, varscan2
- SLC25A14 | c.929A>T p.N310I | Missense Mutation (SNP) | VAF 121/171 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54417696; called by muse, mutect2, varscan2
- SLC25A38 | c.879T>G p.Y293* | Nonsense Mutation (SNP) | VAF 84/312 reads (27%) | catalogued as CM093170; called by muse, mutect2, varscan2
- SLC43A2 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 128/329 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as rs1459697828; called by muse, mutect2, varscan2
- SLC5A3 | c.473T>A p.L158H | Missense Mutation (SNP) | VAF 136/385 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1366202465; called by muse, mutect2, varscan2
- SLITRK6 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 86/303 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs771630878, COSV68390125; called by muse, mutect2, varscan2
- SOGA3 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as COSV100846857; called by muse, mutect2
- SORL1 | c.2796G>A p.W932* | Nonsense Mutation (SNP) | VAF 105/341 reads (31%) | catalogued as COSV52753812; called by muse, mutect2, varscan2
- SPATA7 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs779479852; called by mutect2, varscan2
- SPP2 | c.380T>G p.V127G | Missense Mutation (SNP) | VAF 102/363 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV51446829; called by muse, mutect2, varscan2
- SPPL3 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 112/365 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as rs748258828, COSV62232713; called by muse, mutect2, varscan2
- STX10 | c.518G>A p.S173N | Missense Mutation (SNP) | VAF 95/312 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs926022582; called by muse, mutect2, varscan2
- SUZ12 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 78/267 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.818); catalogued as rs778990935, COSV59499663; called by muse, mutect2, varscan2
- SVEP1 | c.3176G>A p.G1059D | Missense Mutation (SNP) | VAF 77/230 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221256057; called by muse, mutect2, varscan2
- TAF1L | c.1845G>A p.M615I | Missense Mutation (SNP) | VAF 185/583 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1465736684; called by muse, mutect2, varscan2
- TECPR2 | c.4070C>T p.S1357L | Missense Mutation (SNP) | VAF 85/262 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs754669754; called by muse, mutect2, varscan2
- TFAP2D | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 115/345 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV50428167, COSV50449750; called by muse, mutect2, varscan2
- TFR2 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 61/427 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs142149120; called by muse, mutect2, varscan2
- THRAP3 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 139/382 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV63566846; called by muse, mutect2, varscan2
- TIMELESS | c.2401C>T p.R801* | Nonsense Mutation (SNP) | VAF 85/274 reads (31%) | catalogued as COSV57511764; called by muse, mutect2, varscan2
- TMEM132D | c.2285G>A p.G762E | Missense Mutation (SNP) | VAF 148/424 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99066515; called by muse, mutect2
- TNFSF10 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV53844131; called by muse, mutect2, varscan2
- TRAF2 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 90/323 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56037504; called by muse, mutect2, varscan2
- TRPC7 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 96/308 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV61453665; called by muse, mutect2, varscan2
- TTN | c.40207G>A p.E13403K (on ENST00000591111; = p.E5979K on NM_003319.4) | Missense Mutation (SNP) | VAF 92/283 reads (33%) | PolyPhen probably damaging (0.994); catalogued as COSV60299445; called by muse, mutect2, varscan2
- TTN | c.15056C>T p.S5019F (on ENST00000591111; = p.S4092F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/338 reads (33%) | PolyPhen possibly damaging (0.605); catalogued as COSV60418850; called by muse, mutect2, varscan2
- TTN | c.3165C>T p.R1055= (on ENST00000591111; = p.R1009= on NM_003319.4) | Splice Region (SNP) | VAF 80/234 reads (34%) | catalogued as rs746636600; called by muse, mutect2, varscan2
- TUBGCP6 | c.2042C>T p.S681F | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1204561026; called by muse, mutect2, varscan2
- UGT2B15 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 89/349 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.208); catalogued as rs1468376670; called by muse, mutect2, varscan2
- USP15 | c.2014C>T p.P672S (on ENST00000280377 / NM_001351159.2; = p.P643S on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.03); catalogued as COSV54795502; called by muse, mutect2, varscan2
- USP29 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 84/268 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV104372284, COSV54144575; called by muse, mutect2, varscan2
- VPS9D1 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 99/308 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs764472959; called by muse, mutect2, varscan2
- WDR87 | c.5470G>A p.E1824K | Missense Mutation (SNP) | VAF 15/398 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.155); catalogued as rs1044814380; called by muse, mutect2
- WDR97 | c.4361A>C p.H1454P | Missense Mutation (SNP) | VAF 180/461 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1310414159; called by muse, mutect2, varscan2
- XIRP2 | c.8258C>T p.S2753F (on ENST00000628543; = p.S2928F on NM_152381.6) | Missense Mutation (SNP) | VAF 113/323 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1391326126, COSV54733571; called by muse, mutect2, varscan2
- ZC3H11B | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 93/234 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327788201; called by muse, mutect2, varscan2
- ZFYVE26 | c.6061C>T p.R2021C | Missense Mutation (SNP) | VAF 110/364 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs531708348, COSV61327877; called by muse, mutect2, varscan2
- ZNF471 | c.169A>C p.I57L | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV57293207; called by muse, mutect2, varscan2
- ZNF48 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 122/398 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.145); catalogued as rs987672284; called by muse, mutect2
- ZNF585B | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 106/363 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as rs368332359; called by muse, mutect2, varscan2
- ZNF688 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 131/387 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs1273169448; called by muse, mutect2, varscan2
- ZNF688 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 133/385 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs372723303; called by muse, mutect2, varscan2
- ZPLD1 | c.722G>A p.G241E (on ENST00000466937 / NM_001329788.1; = p.G257E on NM_175056.2) | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.934); catalogued as COSV60351939; called by muse, mutect2, varscan2
- ABCA12 | c.1498G>A p.D500N (on ENST00000272895 / NM_173076.3; = p.D182N on NM_015657.3) | Missense Mutation (SNP) | VAF 74/312 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC12 | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 93/319 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABHD12 | c.1179G>T p.E393D | Missense Mutation (SNP) | VAF 124/317 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAN | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 194/553 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADAMTS13 | c.1969-1G>A p.X657_splice | Splice Site (SNP) | VAF 72/244 reads (30%) | called by muse, mutect2, varscan2
- ADGRA3 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 116/363 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ADH1A | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 105/362 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ADPRS | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 86/398 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AKAP17A | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 186/563 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ALOX5 | c.1449G>A p.R483= | Splice Region (SNP) | VAF 85/321 reads (26%) | called by muse, mutect2, varscan2
- ANK3 | c.7649G>A p.S2550N | Missense Mutation (SNP) | VAF 28/468 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2
- ANKEF1 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 106/329 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP26 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ATG14 | c.1138T>G p.Y380D | Missense Mutation (SNP) | VAF 80/301 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ATOH1 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 131/404 reads (32%) | called by muse, mutect2, varscan2
- ATP6V0D2 | c.1014G>C p.R338S | Missense Mutation (SNP) | VAF 9/266 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- BFSP1 | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 102/373 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- BOLL | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- BST1 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 138/408 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C17orf113 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 132/436 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C8orf34 | c.908G>A p.S303N | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNA1C | c.5644C>T p.P1882S | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- CALHM4 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.927); called by muse, mutect2
- CATSPER3 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 74/256 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CC2D2B | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC27 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 170/494 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CD22 | c.1600A>G p.S534G | Missense Mutation (SNP) | VAF 142/473 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP126 | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 150/364 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CERS6 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHI3L1 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 144/375 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHI3L2 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); called by muse, mutect2
- COL10A1 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- COL27A1 | c.5020C>T p.Q1674* | Nonsense Mutation (SNP) | VAF 114/438 reads (26%) | called by muse, mutect2, varscan2
- COL4A3 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 145/454 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL5A2 | c.1843G>T p.G615C | Missense Mutation (SNP) | VAF 89/277 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COQ2 | c.477G>A p.W159* | Nonsense Mutation (SNP) | VAF 116/405 reads (29%) | called by muse, mutect2, varscan2
- CORIN | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 120/331 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CREBBP | c.4549C>T p.H1517Y | Missense Mutation (SNP) | VAF 83/288 reads (29%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CSF1 | c.1372G>A p.G458R | Missense Mutation (SNP) | VAF 177/507 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CYBRD1 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- CYFIP2 | c.531G>A p.M177I | Missense Mutation (SNP) | VAF 96/284 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- DCDC1 | c.2699G>A p.S900N (on ENST00000597505 / NM_001367979.1; = p.S7N on NM_020869.3) | Missense Mutation (SNP) | VAF 108/326 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DHX37 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 84/289 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DIAPH2 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 86/143 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH5 | c.4493G>A p.R1498K | Missense Mutation (SNP) | VAF 111/339 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DNMT1 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 90/337 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- DOCK10 | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 94/334 reads (28%) | called by muse, mutect2, varscan2
- DOP1B | c.4013T>A p.I1338N | Missense Mutation (SNP) | VAF 123/356 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- DPH7 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 125/404 reads (31%) | called by muse, mutect2, varscan2
- DTNA | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- EBF2 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 100/325 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELOA3 | c.813G>A p.W271* | Nonsense Mutation (SNP) | VAF 72/1370 reads (5%) | called by muse, mutect2
- EML5 | c.4144T>A p.Y1382N (on ENST00000380664; = p.Y1390N on NM_183387.3) | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ENGASE | c.573C>A p.F191L | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- EYA4 | c.81C>T p.S27= | Splice Region (SNP) | VAF 55/165 reads (33%) | called by muse, mutect2, varscan2
- F5 | c.5908G>A p.E1970K | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- F7 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 98/343 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- FAM133B | c.450_451del p.E151Ifs*4 | Frame Shift Del (DEL) | VAF 47/246 reads (19%) | called by mutect2, pindel, varscan2
- FAM135B | c.2779G>A p.E927K | Missense Mutation (SNP) | VAF 137/411 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- FDXR | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 100/266 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FER1L6 | c.1890A>T p.K630N | Missense Mutation (SNP) | VAF 66/213 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by mutect2, varscan2
- FETUB | c.379A>T p.S127C | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- FLNC | c.5131C>T p.P1711S | Missense Mutation (SNP) | VAF 134/674 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- FSIP2 | c.1610G>A p.R537K | Missense Mutation (SNP) | VAF 70/264 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FSIP2 | c.8941T>G p.S2981A | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- GAK | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 99/281 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- GATAD2A | c.1500G>A p.Q500= | Splice Region (SNP) | VAF 90/300 reads (30%) | called by muse, mutect2, varscan2
- GEMIN5 | c.3754C>T p.P1252S | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GNAS | c.562G>C p.G188R | Missense Mutation (SNP) | VAF 123/354 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- GNAS | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 156/518 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GNB5 | c.296G>A p.R99K (on ENST00000261837 / NM_016194.4; = p.R57K on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/497 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- GOLGA6B | c.744G>A p.W248* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- GOLGA6L7 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 67/448 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2
- GOLGA8Q | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 120/759 reads (16%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR179 | c.1899G>A p.W633* (on ENST00000621958; = p.W632* on NM_001004334.4) | Nonsense Mutation (SNP) | VAF 118/347 reads (34%) | called by muse, mutect2, varscan2
- GPRIN2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 62/444 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- GREM1 | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 152/452 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GRM8 | c.1495G>A p.V499M | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GTPBP4 | c.1342A>G p.K448E | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERC2 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 134/423 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- HERC5 | c.415A>T p.K139* | Nonsense Mutation (SNP) | VAF 47/206 reads (23%) | called by muse, mutect2, varscan2
- HIVEP1 | c.6565_6588del p.E2189_D2196del | In Frame Del (DEL) | VAF 85/297 reads (29%) | called by mutect2, pindel, varscan2
- HLA-DMA | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 210/649 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HP | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 65/235 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- HSFX1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.95); called by mutect2, varscan2
- IGHM | c.126G>A p.W42* | Nonsense Mutation (SNP) | VAF 92/264 reads (35%) | called by muse, mutect2, varscan2
- IGSF10 | c.6362C>T p.A2121V | Missense Mutation (SNP) | VAF 106/339 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KANK4 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- KIF3B | c.1831C>T p.H611Y | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLF18 | c.2921C>T p.S974F | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- KLHL38 | c.94A>C p.I32L | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- KLK11 | c.470C>T p.A157V (on ENST00000594768 / NM_144947.3; = p.A125V on NM_006853.3) | Missense Mutation (SNP) | VAF 135/443 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- KLRG1 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 63/300 reads (21%) | called by muse, mutect2, varscan2
- KRT86 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- L3HYPDH | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 165/505 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LEPR | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC26 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 180/548 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- LTBP1 | c.4217G>T p.G1406V (on ENST00000404816 / NM_206943.4; = p.G1080V on NM_000627.4) | Missense Mutation (SNP) | VAF 86/272 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by mutect2, varscan2
- LYPD6 | c.145T>G p.C49G | Missense Mutation (SNP) | VAF 76/203 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MAGEA1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 112/171 reads (65%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K1 | c.1731G>A p.W577* | Nonsense Mutation (SNP) | VAF 106/304 reads (35%) | called by muse, mutect2, varscan2
- MBD3 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 132/453 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MEGF8 | c.6532C>T p.P2178S (on ENST00000251268 / NM_001271938.2; = p.P2111S on NM_001410.3) | Missense Mutation (SNP) | VAF 160/463 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- MEI4 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 50/187 reads (27%) | called by muse, mutect2, varscan2
- MET | c.4126G>A p.D1376N | Missense Mutation (SNP) | VAF 98/473 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MGAT4A | c.1128+1G>A p.X376_splice | Splice Site (SNP) | VAF 67/235 reads (29%) | called by muse, mutect2, varscan2
- MGAT4A | c.1128G>A p.T376= | Splice Region (SNP) | VAF 68/240 reads (28%) | called by muse, mutect2, varscan2
- MINDY4 | c.1321A>C p.T441P | Missense Mutation (SNP) | VAF 90/385 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- MMP26 | c.532A>T p.N178Y | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTFR2 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 75/202 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MYH4 | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 158/522 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYL4 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 136/386 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- MYO1F | c.2234G>A p.G745E | Missense Mutation (SNP) | VAF 162/456 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYRF | c.229C>T p.P77S (on ENST00000278836 / NM_001127392.3; = p.P68S on NM_013279.4) | Missense Mutation (SNP) | VAF 178/583 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NCOA2 | c.2039G>A p.G680E | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- NDUFB4 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- NEBL | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NEFH | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 115/181 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NID2 | c.2776G>A p.G926R | Missense Mutation (SNP) | VAF 81/276 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP8 | c.2965A>C p.S989R | Missense Mutation (SNP) | VAF 22/462 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); called by muse, mutect2
- NPHS1 | c.3476C>T p.S1159F | Missense Mutation (SNP) | VAF 117/327 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NPNT | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 174/450 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.033); called by muse, varscan2
- NR5A2 | c.1150G>A p.E384K (on ENST00000367362 / NM_205860.3; = p.E338K on NM_003822.5) | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- NUTM2D | c.745G>C p.D249H | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- OPRPN | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 94/316 reads (30%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10AC1 | c.413G>A p.G138D | Missense Mutation (SNP) | VAF 142/781 reads (18%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- OR10G7 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 135/383 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10R2 | c.728G>A p.R243K | Missense Mutation (SNP) | VAF 88/318 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR4K1 | c.926G>A p.W309* | Nonsense Mutation (SNP) | VAF 50/160 reads (31%) | called by muse, mutect2, varscan2
- OR5AS1 | c.919A>T p.R307* | Nonsense Mutation (SNP) | VAF 28/149 reads (19%) | called by muse, mutect2, varscan2
- OR5K4 | c.489A>T p.L163F | Missense Mutation (SNP) | VAF 75/245 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OSTN | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 92/287 reads (32%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OTOA | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 107/341 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- PABPC1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 83/242 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAM | c.639A>T p.E213D | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH19 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 162/249 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB3 | c.1883G>A p.R628K | Missense Mutation (SNP) | VAF 200/653 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- PGLYRP3 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 76/262 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PHC3 | c.1237A>G p.I413V (on ENST00000494943 / NM_001308116.2; = p.I425V on NM_024947.4) | Missense Mutation (SNP) | VAF 112/380 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- PIK3C2G | c.1814G>A p.G605E (on ENST00000676171; = p.G564E on NM_004570.5) | Missense Mutation (SNP) | VAF 93/302 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3R2 | c.1574C>T p.S525F | Missense Mutation (SNP) | VAF 72/250 reads (29%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIP4P2 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 94/307 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PLCXD3 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 97/327 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PLXNC1 | c.530_541del p.L177_A181delinsP | In Frame Del (DEL) | VAF 119/472 reads (25%) | called by mutect2, pindel, varscan2
- PPM1D | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 73/333 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRAMEF26 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 20/576 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); called by muse, mutect2
- PRKCB | c.1087G>A p.G363S | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- RAB3IP | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 93/295 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- RANBP2 | c.9620C>T p.S3207F | Missense Mutation (SNP) | VAF 76/309 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- RAPGEF2 | c.2370T>A p.H790Q | Missense Mutation (SNP) | VAF 110/316 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- RAPSN | c.1162C>T p.L388F | Missense Mutation (SNP) | VAF 161/463 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- RBSN | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- RD3L | c.98A>G p.E33G | Missense Mutation (SNP) | VAF 20/474 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RIT2 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RNF133 | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 293/473 reads (62%) | SIFT tolerated (0.05); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SCGN | c.491A>T p.N164I | Missense Mutation (SNP) | VAF 95/294 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SIRT1 | c.1037A>T p.N346I | Missense Mutation (SNP) | VAF 134/397 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC27A3 | c.523C>T p.R175* (on ENST00000271857; = p.R47* on NM_024330.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 167/509 reads (33%) | called by muse, mutect2, varscan2
- SLC5A3 | c.472C>T p.L158F | Missense Mutation (SNP) | VAF 136/385 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SMC1B | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 92/181 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SMYD3 | c.257A>G p.E86G (on ENST00000490107 / NM_001375962.1; = p.E27G on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/310 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SNX14 | c.950C>T p.P317L (on ENST00000314673 / NM_001350535.1; = p.P273L on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- SPATA18 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 81/257 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SPATA31E1 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 185/537 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPDYE3 | c.97G>T p.G33* | Nonsense Mutation (SNP) | VAF 31/238 reads (13%) | called by muse, mutect2, varscan2
- SRGAP3 | c.2803C>A p.H935N | Missense Mutation (SNP) | VAF 125/360 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SRL | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 109/298 reads (37%) | SIFT tolerated (0.86); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- SRPK3 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 205/266 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STAP1 | c.330A>T p.E110D | Missense Mutation (SNP) | VAF 72/267 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2359_2359+1insTACAG p.A787Vfs*5 | Frame Shift Ins (INS) | VAF 65/176 reads (37%) | called by mutect2, pindel, varscan2
- STRA8 | c.710C>T p.S237L (on ENST00000275764; = p.S215L on NM_182489.2) | Missense Mutation (SNP) | VAF 399/674 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SUN3 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 87/197 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNE2 | c.18722G>A p.R6241K | Missense Mutation (SNP) | VAF 77/228 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SYNJ1 | c.4319C>T p.T1440I | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYT3 | c.1450A>T p.K484* | Nonsense Mutation (SNP) | VAF 29/449 reads (6%) | called by muse, mutect2
- TANC1 | c.260-1G>A p.X87_splice | Splice Site (SNP) | VAF 78/254 reads (31%) | called by muse, mutect2, varscan2
- TASP1 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 89/323 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TBX18 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 126/359 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- TDRD12 | c.2233A>G p.T745A | Missense Mutation (SNP) | VAF 123/385 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- TDRD6 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 160/512 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TENM4 | c.856C>T p.L286F | Missense Mutation (SNP) | VAF 88/295 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TET1 | c.779T>C p.V260A | Missense Mutation (SNP) | VAF 26/389 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2
- THRA | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 100/277 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TJP3 | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 130/383 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TLL1 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAPPC3 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 133/394 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRHDE | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 123/343 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSPAN15 | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 68/236 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- UGT2B4 | c.497T>C p.I166T | Missense Mutation (SNP) | VAF 103/299 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- URB1 | c.6596C>T p.S2199F | Missense Mutation (SNP) | VAF 22/425 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2
- VWDE | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 132/305 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- WDR81 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 203/591 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WEE2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 100/545 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WNK2 | c.6458A>G p.N2153S (on ENST00000297954 / NM_001282394.1; = p.N2116S on NM_006648.3) | Missense Mutation (SNP) | VAF 174/520 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- WNT16 | c.620A>G p.E207G (on ENST00000222462 / NM_057168.2; = p.E197G on NM_016087.2) | Missense Mutation (SNP) | VAF 167/339 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- XKR5 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 155/443 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- XPNPEP1 | c.1256T>C p.F419S | Missense Mutation (SNP) | VAF 106/299 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZBTB4 | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 130/414 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF146 | c.734G>A p.C245Y | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF292 | c.7754C>A p.S2585Y | Missense Mutation (SNP) | VAF 111/331 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF483 | c.552G>A p.W184* | Nonsense Mutation (SNP) | VAF 104/323 reads (32%) | called by muse, mutect2, varscan2
- ZNF486 | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- ZNF510 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 67/241 reads (28%) | called by muse, mutect2, varscan2
- ZNF569 | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 112/356 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF701 | c.1240C>T p.H414Y (on ENST00000301093; = p.H348Y on NM_018260.3) | Missense Mutation (SNP) | VAF 135/434 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- ZNF804B | c.2996G>A p.R999K | Missense Mutation (SNP) | VAF 84/374 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZSWIM5 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, varscan2
- AAGAB | c.807A>G p.L269= | Silent (SNP) | VAF 75/221 reads (34%) | called by muse, mutect2, varscan2
- ADAM18 | c.1401C>T p.T467= | Silent (SNP) | VAF 125/387 reads (32%) | catalogued as COSV55843387; called by muse, mutect2, varscan2
- ADAM7 | c.2238C>T p.I746= | Silent (SNP) | VAF 86/285 reads (30%) | catalogued as rs765791653, COSV51535930; called by muse, mutect2, varscan2
- ADGRB3 | c.4095A>G p.Q1365= | Silent (SNP) | VAF 105/341 reads (31%) | catalogued as COSV53243735; called by muse, mutect2, varscan2
- AHCTF1 | c.4041C>T p.I1347= (on ENST00000366508; = p.I1321= on NM_015446.5) | Silent (SNP) | VAF 117/364 reads (32%) | catalogued as COSV58253925; called by muse, mutect2, varscan2
- ANAPC2 | c.1158C>T p.L386= | Silent (SNP) | VAF 82/292 reads (28%) | catalogued as COSV100119111; called by muse, mutect2, varscan2
- ANK3 | c.9135C>T p.P3045= | Silent (SNP) | VAF 121/379 reads (32%) | called by muse, mutect2, varscan2
- ANO1 | c.1212C>T p.F404= | Silent (SNP) | VAF 123/402 reads (31%) | catalogued as rs763696945, COSV60287870; called by muse, mutect2, varscan2
- AP2A1 | c.552C>T p.P184= | Silent (SNP) | VAF 106/357 reads (30%) | catalogued as rs777106067, COSV100756148; called by muse, mutect2, varscan2
- APBB1IP | c.864G>A p.E288= | Silent (SNP) | VAF 32/191 reads (17%) | catalogued as COSV66131278; called by muse, mutect2, varscan2
- ARHGEF26 | c.2121C>T p.S707= | Silent (SNP) | VAF 66/282 reads (23%) | called by muse, mutect2, varscan2
- ARHGEF35 | c.684A>G p.Q228= | Silent (SNP) | VAF 12/94 reads (13%) | called by mutect2, varscan2
- ATP6V1G3 | c.150G>A p.Q50= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as COSV55280574; called by muse, varscan2
- ATXN2L | c.2670C>T p.A890= | Silent (SNP) | VAF 76/334 reads (23%) | catalogued as rs774866719; called by muse, mutect2, varscan2
- BAZ2B | c.5853C>T p.G1951= | Silent (SNP) | VAF 103/354 reads (29%) | catalogued as rs774643086; called by muse, mutect2, varscan2
- BCORL1 | c.3984G>A p.K1328= | Silent (SNP) | VAF 31/318 reads (10%) | called by muse, mutect2, varscan2
- BCORL1 | c.3985A>C p.R1329= | Silent (SNP) | VAF 30/318 reads (9%) | called by muse, mutect2, varscan2
- BICRA | c.2946C>T p.A982= | Silent (SNP) | VAF 157/517 reads (30%) | called by muse, mutect2, varscan2
- CAPN6 | c.171C>T p.I57= | Silent (SNP) | VAF 61/120 reads (51%) | called by muse, mutect2, varscan2
- CBLC | c.1311C>T p.P437= | Silent (SNP) | VAF 140/471 reads (30%) | called by muse, mutect2, varscan2
- CENPT | c.1647C>T p.P549= | Silent (SNP) | VAF 91/278 reads (33%) | catalogued as rs747793045; called by muse, mutect2, varscan2
- CHAMP1 | c.1590G>T p.L530= | Silent (SNP) | VAF 115/446 reads (26%) | called by muse, mutect2, varscan2
- CHD3 | c.2970C>T p.P990= | Silent (SNP) | VAF 91/189 reads (48%) | catalogued as COSV100391272; called by muse, mutect2, varscan2
- CHST6 | c.483C>T p.A161= | Silent (SNP) | VAF 141/448 reads (31%) | called by muse, mutect2, varscan2
- CIB3 | c.219G>A p.R73= | Silent (SNP) | VAF 98/313 reads (31%) | called by muse, mutect2, varscan2
- COL4A6 | c.3822C>A p.G1274= | Silent (SNP) | VAF 147/238 reads (62%) | catalogued as rs752945513; called by muse, mutect2, varscan2
- CR1 | c.420C>T p.S140= | Silent (SNP) | VAF 53/237 reads (22%) | called by muse, mutect2, varscan2
- CSMD1 | c.9924C>T p.F3308= (on ENST00000520002; = p.F3307= on NM_033225.6) | Silent (SNP) | VAF 107/328 reads (33%) | catalogued as rs753525110, COSV59294648; called by muse, mutect2, varscan2
- CSMD2 | c.1998C>T p.L666= | Silent (SNP) | VAF 124/363 reads (34%) | catalogued as rs199900835, COSV53898119; called by muse, mutect2, varscan2
- DAB1 | c.117G>T p.G39= | Silent (SNP) | VAF 32/300 reads (11%) | called by muse, mutect2, varscan2
- DIDO1 | c.5281T>C p.L1761= | Silent (SNP) | VAF 158/455 reads (35%) | called by muse, mutect2, varscan2
- DLX3 | c.843C>T p.P281= | Silent (SNP) | VAF 133/389 reads (34%) | called by muse, mutect2, varscan2
- DNAH10 | c.2232G>A p.L744= (on ENST00000409039; = p.L683= on NM_207437.3) | Silent (SNP) | VAF 139/416 reads (33%) | called by muse, mutect2, varscan2
- DNAH12 | c.7914G>A p.K2638= (on ENST00000351747; = p.K3506= on NM_001366028.2) | Silent (SNP) | VAF 81/226 reads (36%) | called by muse, mutect2, varscan2
- DSP | c.1425C>T p.I475= | Silent (SNP) | VAF 85/272 reads (31%) | catalogued as rs1329910838, COSV65791403; called by muse, mutect2, varscan2
- EEF1A2 | c.75C>T p.G25= | Silent (SNP) | VAF 134/420 reads (32%) | called by muse, mutect2, varscan2
- EIF2AK4 | c.3939C>T p.I1313= | Silent (SNP) | VAF 102/271 reads (38%) | called by muse, mutect2, varscan2
- FAM83F | c.921G>A p.A307= | Silent (SNP) | VAF 145/264 reads (55%) | catalogued as rs139637555; called by muse, mutect2, varscan2
- FGFR4 | c.2121G>A p.R707= | Silent (SNP) | VAF 120/442 reads (27%) | catalogued as COSV99451079; called by muse, mutect2, varscan2
- FIS1 | c.384C>T p.I128= | Silent (SNP) | VAF 108/499 reads (22%) | called by muse, varscan2
- FNDC3B | c.3351C>T p.T1117= | Silent (SNP) | VAF 26/407 reads (6%) | catalogued as COSV100394136; called by muse, mutect2
- GABRB2 | c.951C>T p.F317= | Silent (SNP) | VAF 107/306 reads (35%) | catalogued as COSV50906470; called by muse, mutect2, varscan2
- GABRG3 | c.804G>A p.V268= | Silent (SNP) | VAF 83/315 reads (26%) | called by muse, mutect2, varscan2
- GBA | c.240G>A p.E80= | Silent (SNP) | VAF 176/493 reads (36%) | catalogued as rs76337315; called by muse, mutect2, varscan2
- GHSR | c.90G>A p.L30= | Silent (SNP) | VAF 159/459 reads (35%) | catalogued as rs1183626108; called by muse, mutect2, varscan2
- GNAS | c.1056C>T p.P352= | Silent (SNP) | VAF 155/517 reads (30%) | called by muse, mutect2, varscan2
- GPR68 | c.570C>T p.F190= | Silent (SNP) | VAF 150/444 reads (34%) | catalogued as COSV53175557; called by muse, mutect2, varscan2
- GPRASP2 | c.1584C>T p.P528= | Silent (SNP) | VAF 143/215 reads (67%) | called by muse, mutect2, varscan2
- GRIN3B | c.561G>A p.L187= | Silent (SNP) | VAF 161/509 reads (32%) | called by muse, mutect2, varscan2
- GRM5 | c.975C>T p.I325= | Silent (SNP) | VAF 79/294 reads (27%) | called by muse, mutect2, varscan2
- HDC | c.312C>T p.F104= | Silent (SNP) | VAF 44/175 reads (25%) | catalogued as COSV51069440; called by muse, mutect2, varscan2
- HEPACAM2 | c.765G>A p.G255= (on ENST00000394468 / NM_001039372.4; = p.G243= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/468 reads (4%) | catalogued as rs1256271690; called by muse, mutect2
- HHEX | c.654G>A p.R218= | Silent (SNP) | VAF 143/375 reads (38%) | called by muse, mutect2, varscan2
- IGHM | c.1086C>T p.F362= | Silent (SNP) | VAF 159/436 reads (36%) | catalogued as rs1382640429; called by muse, mutect2, varscan2
- IGLV11-55 | c.324G>A p.E108= | Silent (SNP) | VAF 69/143 reads (48%) | catalogued as COSV101135356; called by muse, mutect2, varscan2
- IGSF10 | c.1695G>A p.R565= | Silent (SNP) | VAF 96/355 reads (27%) | catalogued as rs758154653, COSV56782287; called by muse, mutect2, varscan2
- IL18R1 | c.933C>T p.F311= | Silent (SNP) | VAF 80/264 reads (30%) | called by muse, mutect2, varscan2
- INHBA | c.423C>T p.S141= | Silent (SNP) | VAF 105/434 reads (24%) | called by muse, mutect2, varscan2
- INPP5D | c.1758G>A p.G586= (on ENST00000445964 / NM_001017915.3; = p.G585= on NM_005541.5) | Silent (SNP) | VAF 120/346 reads (35%) | catalogued as COSV64040363; called by muse, mutect2, varscan2
- ITGB3 | c.1356C>T p.I452= | Silent (SNP) | VAF 129/412 reads (31%) | catalogued as rs868493250, COSV71383686; called by muse, mutect2, varscan2
- ITPR1 | c.3270G>A p.Q1090= (on ENST00000354582; = p.Q1075= on NM_002222.7) | Silent (SNP) | VAF 110/353 reads (31%) | called by muse, mutect2, varscan2
- JMJD6 | c.573G>A p.L191= | Silent (SNP) | VAF 154/401 reads (38%) | called by muse, mutect2, varscan2
- KANSL3 | c.141C>T p.A47= | Silent (SNP) | VAF 107/368 reads (29%) | catalogued as rs921771680; called by muse, mutect2, varscan2
- KATNIP | c.1773G>A p.K591= | Silent (SNP) | VAF 104/292 reads (36%) | called by muse, mutect2, varscan2
- KIF5C | c.2661G>A p.K887= | Silent (SNP) | VAF 192/578 reads (33%) | called by muse, mutect2, varscan2
- KLF18 | c.1716G>A p.G572= | Silent (SNP) | VAF 196/554 reads (35%) | called by muse, varscan2
- KLHL8 | c.123C>T p.S41= | Silent (SNP) | VAF 115/357 reads (32%) | called by muse, mutect2, varscan2
- KNDC1 | c.3735G>A p.Q1245= | Silent (SNP) | VAF 172/523 reads (33%) | catalogued as rs757488436, COSV100466152; called by muse, mutect2, varscan2
- LILRA4 | c.159G>A p.L53= | Silent (SNP) | VAF 102/368 reads (28%) | called by muse, mutect2, varscan2
- LIMK1 | c.666G>A p.R222= | Silent (SNP) | VAF 220/430 reads (51%) | called by muse, mutect2, varscan2
- LRP1B | c.2640C>T p.N880= | Silent (SNP) | VAF 66/194 reads (34%) | catalogued as rs1320343499, COSV63341852; called by muse, mutect2, varscan2
- LTBP2 | c.1278C>T p.F426= | Silent (SNP) | VAF 26/592 reads (4%) | called by muse, mutect2
- MAGEA1 | c.54C>T p.A18= | Silent (SNP) | VAF 112/171 reads (65%) | called by muse, mutect2, varscan2
- MANEAL | c.933C>T p.T311= (on ENST00000373045 / NM_001113482.1; = p.T89= on NM_152496.2) | Silent (SNP) | VAF 35/600 reads (6%) | called by muse, mutect2
- MAP1A | c.4716G>A p.L1572= | Silent (SNP) | VAF 122/350 reads (35%) | catalogued as rs374749428; called by muse, mutect2, varscan2
- MAP3K13 | c.129C>T p.L43= | Silent (SNP) | VAF 94/292 reads (32%) | catalogued as rs769649241; called by muse, mutect2, varscan2
- MAPK4 | c.873G>A p.K291= | Silent (SNP) | VAF 91/282 reads (32%) | catalogued as rs1311858182; called by muse, mutect2, varscan2
- MBOAT4 | c.192C>T p.F64= | Silent (SNP) | VAF 154/439 reads (35%) | catalogued as COSV57643681; called by muse, mutect2, varscan2
- MDN1 | c.11079C>T p.S3693= | Silent (SNP) | VAF 24/342 reads (7%) | called by muse, mutect2
- MED16 | c.930C>T p.S310= | Silent (SNP) | VAF 102/348 reads (29%) | catalogued as rs369054708; called by muse, mutect2, varscan2
- MED24 | c.2313C>T p.I771= | Silent (SNP) | VAF 125/372 reads (34%) | called by muse, mutect2, varscan2
- MINDY4 | c.1983C>T p.F661= | Silent (SNP) | VAF 85/400 reads (21%) | called by muse, mutect2, varscan2
- MPP2 | c.1281C>T p.S427= (on ENST00000461854 / NM_001278372.2; = p.S403= on NM_005374.5) | Silent (SNP) | VAF 161/477 reads (34%) | catalogued as rs368406948; called by muse, mutect2, varscan2
- MRO | c.399C>T p.I133= | Silent (SNP) | VAF 67/244 reads (27%) | catalogued as rs748949733, COSV56497137; called by muse, mutect2, varscan2
- MXRA5 | c.5619C>T p.F1873= | Silent (SNP) | VAF 117/169 reads (69%) | called by muse, mutect2, varscan2
- MYH4 | c.5109G>A p.R1703= | Silent (SNP) | VAF 112/340 reads (33%) | catalogued as COSV99700304; called by muse, mutect2, varscan2
- MYT1L | c.3381C>T p.I1127= | Silent (SNP) | VAF 20/416 reads (5%) | called by muse, mutect2
- NANOGNB | c.279G>A p.R93= | Silent (SNP) | VAF 112/385 reads (29%) | called by muse, mutect2, varscan2
- NCAM1 | c.1455G>A p.G485= (on ENST00000316851 / NM_181351.5; = p.G475= on NM_000615.7) | Silent (SNP) | VAF 88/305 reads (29%) | catalogued as rs372351899; called by muse, mutect2, varscan2
- NCK2 | c.528C>T p.S176= | Silent (SNP) | VAF 144/477 reads (30%) | called by muse, mutect2, varscan2
- NEB | c.2898C>T p.S966= | Silent (SNP) | VAF 65/238 reads (27%) | called by muse, mutect2, varscan2
- NEFL | c.1179G>A p.L393= | Silent (SNP) | VAF 68/231 reads (29%) | called by muse, mutect2, varscan2
- NLRP2 | c.1707G>A p.L569= | Silent (SNP) | VAF 158/494 reads (32%) | catalogued as rs201116868, COSV99672673; called by muse, mutect2, varscan2
- NLRP7 | c.1206C>T p.F402= | Silent (SNP) | VAF 194/658 reads (29%) | catalogued as rs762472213; called by muse, mutect2, varscan2
- NMUR1 | c.876G>A p.R292= | Silent (SNP) | VAF 93/266 reads (35%) | called by muse, mutect2, varscan2
- NOP9 | c.879C>T p.P293= | Silent (SNP) | VAF 109/352 reads (31%) | catalogued as rs924307383; called by muse, mutect2, varscan2
- NOS1 | c.1791G>A p.E597= | Silent (SNP) | VAF 106/315 reads (34%) | called by muse, mutect2, varscan2
- NRROS | c.277C>T p.L93= | Silent (SNP) | VAF 150/498 reads (30%) | called by muse, mutect2, varscan2
- OPRK1 | c.813G>A p.R271= | Silent (SNP) | VAF 143/440 reads (33%) | catalogued as COSV55571827; called by muse, mutect2, varscan2
- OR10G4 | c.6C>T p.S2= | Silent (SNP) | VAF 16/332 reads (5%) | called by muse, mutect2
- OR10G7 | c.93G>A p.V31= | Silent (SNP) | VAF 135/382 reads (35%) | called by muse, mutect2, varscan2
- OR2B11 | c.777G>A p.A259= | Silent (SNP) | VAF 129/411 reads (31%) | catalogued as rs368167912; called by muse, mutect2
- OR2T11 | c.900G>A p.K300= | Silent (SNP) | VAF 73/242 reads (30%) | called by muse, mutect2, varscan2
- OR4C46 | c.372C>T p.I124= | Silent (SNP) | VAF 105/290 reads (36%) | called by muse, mutect2
- OR4D11 | c.663C>T p.I221= | Silent (SNP) | VAF 109/333 reads (33%) | catalogued as COSV57586011; called by muse, mutect2, varscan2
- OR4E2 | c.927G>A p.T309= | Silent (SNP) | VAF 78/227 reads (34%) | catalogued as rs975852343, COSV57731591; called by muse, mutect2, varscan2
- OR4K1 | c.669C>T p.I223= | Silent (SNP) | VAF 66/222 reads (30%) | catalogued as rs141997601, COSV53459749; called by muse, mutect2, varscan2
- OR4S1 | c.486T>C p.V162= | Silent (SNP) | VAF 135/399 reads (34%) | called by muse, mutect2, varscan2
- OR51E2 | c.516C>T p.V172= | Silent (SNP) | VAF 137/437 reads (31%) | called by muse, mutect2, varscan2
- OR51T1 | c.330C>T p.S110= | Silent (SNP) | VAF 116/383 reads (30%) | called by muse, mutect2, varscan2
- OR5D13 | c.944G>A p.*315= | Silent (SNP) | VAF 35/104 reads (34%) | called by muse, mutect2, varscan2
- OR5T2 | c.630C>A p.A210= | Silent (SNP) | VAF 22/488 reads (5%) | called by muse, mutect2
- OR5T3 | c.696C>T p.F232= | Silent (SNP) | VAF 146/418 reads (35%) | catalogued as COSV100282735, COSV100282964; called by muse, mutect2, varscan2
- PABPC1 | c.411C>T p.S137= | Silent (SNP) | VAF 83/245 reads (34%) | catalogued as rs768199034; called by muse, mutect2, varscan2
- PCDH15 | c.4176C>T p.I1392= | Silent (SNP) | VAF 62/280 reads (22%) | catalogued as COSV100214575, COSV57363336; called by muse, mutect2, varscan2
- PCDHB2 | c.351G>A p.Q117= | Silent (SNP) | VAF 123/398 reads (31%) | called by muse, mutect2, varscan2
- PDE3A | c.804G>A p.R268= | Silent (SNP) | VAF 113/331 reads (34%) | called by muse, mutect2, varscan2
- PDE6A | c.1125G>A p.L375= | Silent (SNP) | VAF 80/260 reads (31%) | catalogued as COSV99678479; called by muse, mutect2, varscan2
- PDE8B | c.1053C>T p.S351= | Silent (SNP) | VAF 115/368 reads (31%) | catalogued as rs753464504, COSV99366571; called by muse, varscan2
- PLIN1 | c.171C>T p.A57= | Silent (SNP) | VAF 114/391 reads (29%) | catalogued as rs771483062; called by muse, mutect2, varscan2
- PLXNA4 | c.1638G>A p.K546= | Silent (SNP) | VAF 95/519 reads (18%) | catalogued as COSV100327054; called by muse, mutect2, varscan2
- PRDX5 | c.45T>C p.Y15= | Silent (SNP) | VAF 124/381 reads (33%) | called by muse, mutect2, varscan2
- PRKCA | c.228G>A p.K76= | Silent (SNP) | VAF 88/303 reads (29%) | called by muse, mutect2, varscan2
- PROKR2 | c.721C>T p.L241= | Silent (SNP) | VAF 135/422 reads (32%) | catalogued as rs756977222; called by muse, mutect2, varscan2
- PSD | c.27C>T p.C9= | Silent (SNP) | VAF 80/294 reads (27%) | catalogued as rs747239250; ClinVar: likely benign; called by muse, mutect2
- PSG7 | c.921C>T p.P307= | Silent (SNP) | VAF 147/476 reads (31%) | catalogued as rs541676662; called by muse, varscan2
- QPCT | c.1050C>T p.I350= | Silent (SNP) | VAF 100/292 reads (34%) | called by muse, mutect2, varscan2
- RDH16 | c.231G>A p.L77= | Silent (SNP) | VAF 135/398 reads (34%) | called by muse, mutect2, varscan2
- RGPD4 | c.1521C>T p.H507= | Silent (SNP) | VAF 126/414 reads (30%) | called by muse, mutect2
- RPH3A | c.1662C>T p.I554= (on ENST00000389385 / NM_001143854.2; = p.I550= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 106/372 reads (28%) | called by muse, mutect2, varscan2
- RTN4R | c.1374C>T p.T458= | Silent (SNP) | VAF 126/268 reads (47%) | catalogued as rs745415553; called by muse, mutect2, varscan2
- SAMHD1 | c.1629C>T p.F543= (on ENST00000262878 / NM_001363729.2; = p.F578= on NM_015474.4) | Silent (SNP) | VAF 77/212 reads (36%) | catalogued as rs1183893558, COSV53433264; called by muse, mutect2, varscan2
- SCN5A | c.4407C>T p.I1469= (on ENST00000333535 / NM_198056.3; = p.I1468= on NM_000335.5) | Silent (SNP) | VAF 59/218 reads (27%) | catalogued as COSV61136689; called by muse, mutect2, varscan2
- SDSL | c.27C>T p.A9= | Silent (SNP) | VAF 117/348 reads (34%) | catalogued as COSV100615216; called by muse, mutect2, varscan2
- SERPINA7 | c.372G>A p.K124= | Silent (SNP) | VAF 139/218 reads (64%) | catalogued as COSV59667338; called by muse, mutect2, varscan2
- SFTPD | c.981C>T p.P327= | Silent (SNP) | VAF 25/471 reads (5%) | catalogued as rs751074112; called by muse, mutect2
- SGIP1 | c.1062C>T p.P354= | Silent (SNP) | VAF 180/492 reads (37%) | catalogued as rs763818478; called by muse, mutect2, varscan2
- SH2B2 | c.264C>T p.F88= | Silent (SNP) | VAF 159/802 reads (20%) | called by muse, mutect2, varscan2
- SLAMF9 | c.282C>T p.S94= | Silent (SNP) | VAF 126/386 reads (33%) | called by muse, mutect2, varscan2
- SLC15A3 | c.1560C>T p.P520= | Silent (SNP) | VAF 130/426 reads (31%) | catalogued as rs756444074, COSV99137837; called by muse, mutect2, varscan2
- SLC8A3 | c.810C>T p.H270= | Silent (SNP) | VAF 91/348 reads (26%) | catalogued as COSV63526203; called by muse, mutect2, varscan2
- SMARCA4 | c.1056C>T p.I352= | Silent (SNP) | VAF 191/638 reads (30%) | called by muse, mutect2, varscan2
- SOS2 | c.2142C>T p.S714= | Silent (SNP) | VAF 72/217 reads (33%) | called by muse, mutect2, varscan2
- SOWAHC | c.1260C>T p.P420= | Silent (SNP) | VAF 99/357 reads (28%) | catalogued as COSV100453882; called by muse, mutect2, varscan2
- SPATA18 | c.543G>A p.E181= | Silent (SNP) | VAF 79/253 reads (31%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.1815G>A p.K605= | Silent (SNP) | VAF 96/523 reads (18%) | called by muse, mutect2, varscan2
- SPDYE3 | c.96G>A p.S32= | Silent (SNP) | VAF 30/234 reads (13%) | catalogued as rs771012048; called by muse, varscan2
- SPINT1 | c.1092C>T p.S364= (on ENST00000344051 / NM_181642.3; = p.S348= on NM_003710.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 107/294 reads (36%) | catalogued as rs1245034856; called by muse, mutect2, varscan2
- SPPL3 | c.1092C>T p.L364= | Silent (SNP) | VAF 111/363 reads (31%) | called by muse, mutect2, varscan2
- SPTAN1 | c.6366C>T p.S2122= | Silent (SNP) | VAF 118/419 reads (28%) | called by muse, mutect2, varscan2
- SRGAP3 | c.2697C>T p.I899= | Silent (SNP) | VAF 140/448 reads (31%) | catalogued as rs1232063428; called by muse, mutect2, varscan2
- SULT2B1 | c.858G>T p.T286= (on ENST00000201586 / NM_177973.2; = p.T271= on NM_004605.2) | Silent (SNP) | VAF 144/407 reads (35%) | catalogued as rs200065856; called by muse, mutect2
- SVEP1 | c.6810C>T p.I2270= | Silent (SNP) | VAF 81/273 reads (30%) | called by muse, mutect2, varscan2
- SYT3 | c.1449G>A p.K483= | Silent (SNP) | VAF 29/451 reads (6%) | called by muse, mutect2
- SYT6 | c.327C>T p.P109= (on ENST00000610222 / NM_001366225.1; = p.P24= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 133/509 reads (26%) | called by muse, mutect2, varscan2
- TBRG1 | c.559C>T p.L187= | Silent (SNP) | VAF 100/359 reads (28%) | called by muse, mutect2, varscan2
- TCEA3 | c.951C>T p.N317= | Silent (SNP) | VAF 87/310 reads (28%) | catalogued as COSV71531851; called by muse, mutect2, varscan2
- THRA | c.423C>T p.N141= | Silent (SNP) | VAF 101/277 reads (36%) | catalogued as rs1251337875; called by muse, mutect2, varscan2
- TIMM44 | c.816C>T p.F272= | Silent (SNP) | VAF 122/398 reads (31%) | called by muse, mutect2, varscan2
- TLE2 | c.1557C>T p.I519= | Silent (SNP) | VAF 101/301 reads (34%) | catalogued as rs776725070, COSV53583123; called by muse, mutect2, varscan2
- TMEM132E | c.1312C>T p.L438= (on ENST00000321639; = p.L528= on NM_001304438.2) | Silent (SNP) | VAF 124/371 reads (33%) | called by muse, mutect2, varscan2
- TMPRSS4 | c.63A>G p.K21= | Silent (SNP) | VAF 97/299 reads (32%) | called by muse, mutect2, varscan2
- TNC | c.6219G>A p.R2073= | Silent (SNP) | VAF 114/372 reads (31%) | catalogued as rs759128721, COSV60788263; called by muse, mutect2, varscan2
- TOX2 | c.864C>T p.I288= (on ENST00000358131 / NM_001098798.2; = p.I237= on NM_032883.3) | Silent (SNP) | VAF 120/327 reads (37%) | catalogued as rs200547615, COSV57891049; called by muse, mutect2, varscan2
- TPSB2 | c.117G>A p.R39= | Silent (SNP) | VAF 188/511 reads (37%) | called by muse, mutect2, varscan2
- TRIM46 | c.1342C>T p.L448= | Silent (SNP) | VAF 127/376 reads (34%) | called by muse, mutect2, varscan2
- TRIM58 | c.855C>T p.L285= | Silent (SNP) | VAF 67/228 reads (29%) | called by muse, mutect2, varscan2
- TRPC7 | c.508C>T p.L170= | Silent (SNP) | VAF 120/357 reads (34%) | catalogued as COSV100725812; called by muse, mutect2, varscan2
- TSHZ2 | c.1437G>A p.V479= | Silent (SNP) | VAF 84/299 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.5730G>T p.V1910= (on ENST00000591111; = p.V1864= on NM_003319.4) | Silent (SNP) | VAF 70/322 reads (22%) | catalogued as COSV60364666; called by muse, mutect2, varscan2
- UBA2 | c.1467C>T p.I489= | Silent (SNP) | VAF 89/277 reads (32%) | catalogued as rs897956487; called by muse, mutect2, varscan2
- UBA2 | c.1468C>T p.L490= | Silent (SNP) | VAF 84/266 reads (32%) | catalogued as COSV99875869; called by muse, varscan2
- UBXN11 | c.711C>T p.L237= (on ENST00000374221 / NM_183008.2; = p.L204= on NM_145345.2) | Silent (SNP) | VAF 139/403 reads (34%) | called by muse, mutect2, varscan2
- USHBP1 | c.831C>T p.I277= | Silent (SNP) | VAF 110/395 reads (28%) | called by muse, mutect2, varscan2
- VCAN | c.8146C>T p.L2716= | Silent (SNP) | VAF 32/437 reads (7%) | called by muse, mutect2
- VWA3A | c.3555G>A p.*1185= | Silent (SNP) | VAF 25/342 reads (7%) | called by muse, mutect2
- WDR81 | c.2781C>T p.F927= | Silent (SNP) | VAF 148/474 reads (31%) | catalogued as rs771048619, COSV58479993; called by muse, mutect2, varscan2
- XDH | c.780G>A p.G260= | Silent (SNP) | VAF 85/288 reads (30%) | catalogued as COSV65150946; called by muse, mutect2, varscan2
- XRCC1 | c.279C>T p.F93= | Silent (SNP) | VAF 84/289 reads (29%) | catalogued as COSV99486281; called by muse, mutect2, varscan2
- ZNF169 | c.495C>T p.F165= | Silent (SNP) | VAF 137/399 reads (34%) | catalogued as rs757646035; called by muse, mutect2, varscan2
- ZNF316 | c.2604C>T p.F868= | Silent (SNP) | VAF 24/892 reads (3%) | called by muse, mutect2
- ZNF407 | c.24C>T p.P8= | Silent (SNP) | VAF 50/190 reads (26%) | catalogued as rs373134415; called by muse, mutect2, varscan2
- ZNF469 | c.5517C>T p.A1839= (on ENST00000437464; = p.A1867= on NM_001367624.2) | Silent (SNP) | VAF 184/583 reads (32%) | catalogued as COSV71258171; called by muse, mutect2, varscan2
- ZNF480 | c.231C>T p.S77= | Silent (SNP) | VAF 80/252 reads (32%) | called by muse, mutect2, varscan2
- ZNF630 | c.1827C>T p.F609= | Silent (SNP) | VAF 117/175 reads (67%) | called by muse, mutect2, varscan2
- ZRANB3 | c.1725G>A p.T575= | Silent (SNP) | VAF 136/418 reads (33%) | catalogued as rs531673790; called by muse, mutect2, varscan2
- ADRA1A | c.884-8759G>A | Intron (SNP) | VAF 96/256 reads (38%) | called by muse, mutect2, varscan2
- ANKRD29 | c.132+173G>A | Intron (SNP) | VAF 82/261 reads (31%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130914476 T>C | 5'Flank (SNP) | VAF 74/230 reads (32%) | called by muse, mutect2, varscan2
- BSCL2 | chr11:62707181 C>T | 5'Flank (SNP) | VAF 120/384 reads (31%) | called by muse, mutect2, varscan2
- CCDC169 | chr13:36227336 C>T | 3'Flank (SNP) | VAF 109/374 reads (29%) | catalogued as rs753172923; called by muse, mutect2
- CHEK1 | chr11:125625964 G>A | 5'Flank (SNP) | VAF 108/394 reads (27%) | called by muse, mutect2, varscan2
- CPLANE1 | c.353+1256T>C | Intron (SNP) | VAF 65/177 reads (37%) | called by muse, mutect2, varscan2
- ECM1 | c.224-49C>T | Intron (SNP) | VAF 141/484 reads (29%) | called by muse, mutect2, varscan2
- FARSA | chr19:12933769 G>A | 5'Flank (SNP) | VAF 80/224 reads (36%) | called by muse, mutect2, varscan2
- GP6 | c.*673C>T | 3'UTR (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+33313A>C | Intron (SNP) | VAF 57/199 reads (29%) | called by muse, mutect2, varscan2
- LINC00662 | n.622C>T | RNA (SNP) | VAF 90/281 reads (32%) | called by muse, mutect2, varscan2
- MAGI2 | c.2047+82C>T | Intron (SNP) | VAF 66/283 reads (23%) | catalogued as rs781168685; called by muse, mutect2, varscan2
- MAP4 | c.1999+4678A>T | Intron (SNP) | VAF 102/301 reads (34%) | called by muse, mutect2, varscan2
- ZNF528 | c.272-834C>T | Intron (SNP) | VAF 92/272 reads (34%) | catalogued as rs1315650763; called by muse, mutect2, varscan2
